Surgical pathology report (de-identified scan), TCGA case TCGA-CS-4938, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Thomas Jefferson University, specimen TCGA-CS-4938-01B (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS:

1. BRAIN TUMOR: LOW GRADE ASTROCYTOMA, GRADE II OF IV (WHO SCALE), SEE MICROSCOPIC DESCRIPTION , SEE NOTE
2. BRAIN TUMOR: LOW GRADE ASTROCYTOMA, GRADE II OF IV (WHO SCALE), SEE MICROSCOPIC DESCRIPTION, SEE NOTE

Comment:

The proliferation index of this tumor is minimally increased compared to that expected for the upper limit of a grade II astrocytoma. Typically such tumors have a proliferation index between 0 and 3%. The presence of a single mitosis is insufficient to grade this tumor as an anaplastic astrocytoma (grade III of IV). Nevertheless, the somewhat slightly increased proliferation index should prompt close clinical follow-up.

Report Electronically Signed

This diagnostic report has been personally interpreted by the signatory of record.

Microscopic Description:

The tumor consists of a mildly pleomorphic and infiltrative proliferation of astrocytic cells. There is no endothelial proliferation and no necrosis. Very rare mitoses (1 definite) are present. Immunohistochemistry for the proliferation antigen Ki67 was performed as follows. Four 250 x 250 micron fields were examined and the percentage of labeled nuclei determined. Over 1000 cells were counted. The proliferation index ranged from 3.2% to 5.7% with an overall average of 4.2%

Frozen Section Diagnosis:

[page 2 of 3]
[REDACTED]

1. and 2. Glial neoplasm. No anaplasia in these frozen sections.

Clinical History and Diagnosis:
Brain tumor

Source of Specimen:
1: Brain tumor
2: Brain tumor

Gross Description:

[REDACTED]

1. Brain tumor: Received fresh are multiple fragments of red-tan soft tissue measuring 1.4 x 1.2 x 0.5 cm in aggregate. The specimen is representatively sampled and submitted in one cassette for frozen section. Touch preps are made. The remainder of the specimen is entirely submitted in one cassette for permanent section.

Designations:

A. frozen section control
B. remainder of specimen

2. Brain tumor: Received fresh are multiple fragments of red-tan soft tissue measuring 2.0 x 2.0 x 0.6 cm in aggregate. The specimen is representatively sampled and submitted in one cassette for frozen section. Touch preps are made. The remainder of the specimen is entirely submitted in one cassette for permanent section.

Designations:

A. frozen section control
B. remainder of specimen

Histology Laboratory

[REDACTED]
Part 1: Brain tumor
UNSTAINED

Part 2: Brain tumor
UNSTAINED

[page 3 of 3]
[REDACTED]

Patient: [REDACTED]
Specimen: [REDACTED]

Accessioned: [REDACTED]

IMMUNOPATHOLOGY REPORT

EVALUATION:

Immunohistochemistry for the proliferation antigen Ki67 was performed as follows. Four 250 x 250 micron fields were examined and the percentage of labeled nuclei determined. Over 1000 cells were counted. The proliferation index ranged from 3.2% to 5.7% with an overall average of 4.2%. [REDACTED] for a complete description of the light microscopy.

[REDACTED]

Report Electronically Signed

This diagnostic report has been personally interpreted by the signatory of record.

[REDACTED]

Other Case Numbers:

[REDACTED]

Source: NCI Genomic Data Commons file 52c6c800-1f90-431c-a1a7-a92c981921f7 (TCGA-CS-4938.36632FE7-C93D-4CAD-BD58-2D259D36127C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).